Somatic mutation profile of cancer-model specimen HCM-CSHL-0079-C25-85B (3D Organoid; aliquot HCM-CSHL-0079-C25-85B-01D-A78M-36), derived from the primary tumor of HCMI case HCM-CSHL-0079-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.9 years (27,727 days).
Specimen HCM-CSHL-0079-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c75050ec-e5a5-42bd-a881-c3a47de61705.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0079-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0079-C25-11A-11D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78d71a9d-a2d0-4b55-9448-947f3f35449a

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 4, Intron 2, Frame Shift Ins 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JUP | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 239/482 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782440692, CM117932, COSV60278113; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 108/218 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 108/216 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 92/92 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AHCY | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 242/502 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV104372538; called by muse, mutect2, varscan2
- ANKRD62 | c.725A>T p.D242V | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs1248316493; called by muse, mutect2, varscan2
- CHRM4 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 254/525 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.246); catalogued as COSV63126418; called by muse, mutect2, varscan2
- COL16A1 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 186/190 reads (98%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs780498909; called by muse, mutect2, varscan2
- DNAH11 | c.7471C>T p.R2491C | Missense Mutation (SNP) | VAF 96/165 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs267601454, COSV60970751; called by muse, mutect2, varscan2
- EPHA6 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67563189, COSV67575954; called by muse, mutect2, varscan2
- FAT3 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs780305849, COSV99968830; called by muse, mutect2, varscan2
- FBXL18 | c.1336C>T p.R446C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV66668926; called by muse, mutect2, varscan2
- GTF3C3 | c.1762C>T p.L588F | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as rs1407489340, COSV55832163, COSV99826919; called by muse, mutect2, varscan2
- HOOK2 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 119/365 reads (33%) | catalogued as COSV99317923; called by muse, mutect2, varscan2
- KLF6 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 294/647 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99434942; called by muse, mutect2, varscan2
- MUC5AC | c.144dup p.P49Afs*71 | Frame Shift Ins (INS) | VAF 92/266 reads (35%) | catalogued as rs776704266; called by mutect2, pindel, varscan2
- NPIPB11 | c.2638G>A p.V880I | Missense Mutation (SNP) | VAF 173/980 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.699); catalogued as rs533305557, COSV67326758; called by muse, varscan2
- NRXN3 | c.2038G>A p.E680K (on ENST00000335750 / NM_001330195.2; = p.E307K on NM_004796.6) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59754688; called by muse, mutect2, varscan2
- PIK3R1 | c.985C>A p.Q329K (on ENST00000521381 / NM_181523.3; = p.Q59K on NM_181504.4) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1343600424, COSV57141568; called by muse, mutect2, varscan2
- PLCB3 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs981845851, COSV54187917; called by muse, mutect2, varscan2
- PLCL1 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs780048494; called by muse, mutect2, varscan2
- RAD51B | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 148/349 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746531915; called by muse, mutect2, varscan2
- RERE | c.4487G>A p.G1496D | Missense Mutation (SNP) | VAF 34/35 reads (97%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100557304; called by muse, mutect2, varscan2
- SLC22A31 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs575619368; called by muse, mutect2, varscan2
- SPATA31D1 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 73/158 reads (46%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.479); catalogued as rs561516052, COSV61192571; called by muse, mutect2, varscan2
- SPTBN2 | c.3679C>T p.R1227W | Missense Mutation (SNP) | VAF 257/589 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs766811381, COSV59447657; called by muse, mutect2, varscan2
- SSTR2 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 110/209 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1420669745, COSV100192098, COSV100192150; called by muse, mutect2, varscan2
- SYDE1 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.113); catalogued as rs1239698803; called by muse, mutect2, varscan2
- SYNE1 | c.16025C>T p.T5342M (on ENST00000367255 / NM_182961.4; = p.T5271M on NM_033071.3) | Missense Mutation (SNP) | VAF 172/173 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs202105931; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TEX15 | c.3607G>T p.E1203* (on ENST00000256246; = p.E1586* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 8/121 reads (7%) | catalogued as COSV56345906; called by muse, mutect2
- TGFBR2 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1553630235, COSV55444513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRMT1 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 158/234 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs770329038, COSV99679285; called by muse, mutect2, varscan2
- USP40 | c.3184G>T p.E1062* | Nonsense Mutation (SNP) | VAF 92/188 reads (49%) | catalogued as COSV52488861; called by muse, mutect2, varscan2
- ZNF800 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 38/66 reads (58%) | catalogued as COSV56175963; called by muse, mutect2, varscan2
- ARFGEF2 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 280/640 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDCA3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2
- CLMN | c.2708+1G>A p.X903_splice | Splice Site (SNP) | VAF 56/84 reads (67%) | called by muse, varscan2
- CNTLN | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 114/114 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- FRMD4A | c.1138T>C p.S380P | Missense Mutation (SNP) | VAF 163/320 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MLH3 | c.731A>T p.H244L | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXNB2 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOH | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 69/74 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC15A1 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- ZCCHC8 | c.-14_2del | Translation Start Site (DEL) | VAF 110/127 reads (87%) | called by mutect2, pindel, varscan2
- ARMCX5 | c.954C>T p.L318= | Silent (SNP) | VAF 36/36 reads (100%) | called by muse, mutect2, varscan2
- ATP4A | c.1629G>A p.E543= | Silent (SNP) | VAF 107/279 reads (38%) | called by muse, mutect2, varscan2
- COL9A3 | c.1134C>T p.R378= | Silent (SNP) | VAF 200/395 reads (51%) | catalogued as rs138208105; called by muse, mutect2, varscan2
- CYP11B1 | c.1302C>T p.S434= | Silent (SNP) | VAF 376/785 reads (48%) | catalogued as rs768226546, COSV52828210; called by muse, mutect2, varscan2
- GCK | c.543C>T p.V181= | Silent (SNP) | VAF 291/633 reads (46%) | catalogued as rs777964292, COSV60786759, COSV60787925; called by muse, mutect2, varscan2
- KLRD1 | c.66G>A p.S22= | Silent (SNP) | VAF 97/219 reads (44%) | catalogued as rs201930748, COSV60274515, COSV60274655; called by muse, mutect2, varscan2
- KNG1 | c.1296C>T p.G432= | Silent (SNP) | VAF 52/153 reads (34%) | called by muse, mutect2, varscan2
- MC1R | c.357C>A p.V119= | Silent (SNP) | VAF 128/203 reads (63%) | catalogued as rs755222490, COSV59626464; called by muse, mutect2, varscan2
- PCLO | c.7872T>C p.P2624= | Silent (SNP) | VAF 102/208 reads (49%) | catalogued as COSV61613219; called by muse, mutect2, varscan2
- RBM20 | c.1365G>A p.S455= | Silent (SNP) | VAF 135/442 reads (31%) | catalogued as rs1414344349, COSV65706777; called by muse, mutect2, varscan2
- SLC22A13 | c.894T>C p.N298= | Silent (SNP) | VAF 101/101 reads (100%) | catalogued as rs751495301; called by muse, mutect2, varscan2
- TNRC6A | c.1293A>G p.V431= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as rs139673816; called by muse, mutect2, varscan2
- C1QTNF9B | c.167-332G>A | Intron (SNP) | VAF 102/206 reads (50%) | catalogued as rs750294202; called by muse, mutect2, varscan2
- POU2F2 | c.303+6535T>G | Intron (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
